TCGA case TCGA-A5-A2K5 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cf77afe9-3785-45d4-ba2a-61c9cb706225

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 76.8 years (28,057 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage IA; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 752 days (2.1 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 49.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 87 days; Days to treatment end: 129 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 752 days (2.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 162.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 127 kg; Height: 163 cm; BMI: 47.8.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A5-A2K5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 290 mg.
  Slide TCGA-A5-A2K5-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-A5-A2K5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A5-A2K5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form 1: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 1; History colorectal cancer: No; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 752 days; disease-specific survival: no event (censored), 752 days; disease-free interval: no event (censored), 752 days; progression-free interval: no event (censored), 752 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A5-A2K5-01A-11D-A17U-01): tumor purity 0.73, ploidy 2, whole-genome doublings 0.
